Gene-level copy-number profile of tumor specimen TCGA-CN-A49A-01A from TCGA case TCGA-CN-A49A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Palate, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 60.2 years (21,995 days).
Specimen TCGA-CN-A49A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b3a12858-6c72-490e-8866-c7c21f6b8c1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A49A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/494ff53e-5c59-4c17-969e-77936de87a80

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 1,482; copy number 2: 12,862; copy number 3: 22,052; copy number 4: 14,995; copy number 5: 3,288; copy number 6: 1,542; copy number 7: 2,441; copy number 8: 507; copy number 9: 106; copy number 10: 61; copy number 11: 28; copy number 12: 195; copy number 14: 91; copy number 16: 5; copy number 18: 9; copy number 19: 17; copy number 22: 29; copy number 26: 38; copy number 57: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A49A-01A-11D-A24C-01): tumor purity 0.55, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr10:34,109,560–34,815,325, 1 gene (within-gene range 0–11): PARD3.
- chr10:34,488,583–34,943,075, 7 genes: ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P.
- chr11:80,751,200–82,718,299, 10 genes (within-gene range 0–2): LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr13:94,154,193–94,187,991, 1 gene (within-gene range 0–2): GPC6-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,487 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,513,377–174,160,165, 460 genes, copy number 7 (broad region; genes not listed).
- chr1:174,367,105–174,368,039, 1 gene, copy number 7: AL022400.1.
- chr2:106,697,331–127,811,187, 342 genes, copy number 7–26 (within-gene range 3–26) (broad region; genes not listed).
- chr2:132,643,286–132,671,579, 2 genes, copy number 9: LYPD1, AC010974.1.
- chr2:132,685,224–132,816,896, 1 gene, copy number 9 (within-gene range 3–9): AC010974.2.
- chr2:176,495,255–176,930,090, 13 genes, copy number 9: LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P.
- chr2:181,422,154–181,930,738, 10 genes, copy number 8: AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2.
- chr2:184,049,467–187,003,377, 26 genes, copy number 9 (within-gene range 3–9): AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7.
- chr2:187,122,562–187,122,861, 1 gene, copy number 9: RN7SKP42.
- chr3:142,949,164–198,222,513, 953 genes, copy number 7 (broad region; genes not listed).
- chr5:14,872,332–15,266,541, 7 genes, copy number 9 (within-gene range 4–9): AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149.
- chr5:15,500,180–17,670,571, 64 genes, copy number 10–14 (within-gene range 4–14) (broad region; genes not listed).
- chr5:18,886,622–19,234,487, 8 genes, copy number 11: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr5:22,754,227–23,689,386, 9 genes, copy number 10–18: AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr5:73,626,158–73,954,014, 5 genes, copy number 8: ARHGEF28, AC091868.2, AC091868.1, RNU7-196P, AC093283.1.
- chr5:81,413,021–83,582,303, 32 genes, copy number 7 (within-gene range 3–7): SSBP2, AC026726.2, AC026726.1, SEM1P1, ATG10, ATG10-IT1, PPIAP11, ATG10-AS1, RN7SL378P, AC010598.1, RPS23, ATP6AP1L, AC026782.1, AC026782.2, AC008885.2, RPL5P16, AC008885.1, MIR3977, LINC01338, AC108174.1, AC027338.2, ST13P12, AC027338.1, AC104118.1, TMEM167A, SCARNA18, XRCC4, AC094085.1, COQ10BP2, FTH1P9, VCAN, VCAN-AS1.
- chr5:83,940,554–84,384,880, 2 genes, copy number 11 (within-gene range 5–11): EDIL3, RNU6-448P.
- chr7:98,617,285–101,018,949, 127 genes, copy number 8 (broad region; genes not listed).
- chr7:106,208,167–106,770,207, 6 genes, copy number 10–16 (within-gene range 4–16): RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3.
- chr7:129,225,023–129,512,918, 7 genes, copy number 10 (within-gene range 4–10): AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1.
- chr8:47,960,185–49,352,844, 26 genes, copy number 57: MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7.
- chr8:74,599,775–74,823,313, 1 gene, copy number 7 (within-gene range 4–7): MIR2052HG.
- chr8:74,705,693–127,742,951, 759 genes, copy number 7–8 (broad region; genes not listed).
- chr8:127,795,962–127,890,720, 2 genes, copy number 8: MIR1204, AC084123.1.
- chr10:33,909,238–33,917,804, 1 gene, copy number 11: LINC02629.
- chr10:34,201,979–34,202,074, 1 gene, copy number 11: Y_RNA.
- chr10:34,965,069–36,442,392, 28 genes, copy number 7–12: PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr14:36,593,839–40,905,513, 51 genes, copy number 8–18: RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, AL049828.2, AL390800.1.
- chr14:61,187,559–61,550,976, 1 gene, copy number 7 (within-gene range 3–7): PRKCH.
- chr14:61,529,128–63,736,505, 41 genes, copy number 7–8: AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1, AL137918.1, SYT16, COX4I1P1, AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3, AL389895.1, ATP5F1AP4, KCNH5, AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P.
- chr14:63,762,013–63,808,732, 2 genes, copy number 8: AL161670.1, RPS28P1.
- chr14:64,449,106–68,730,218, 85 genes, copy number 7–19 (within-gene range 3–19) (broad region; genes not listed).
- chr14:69,611,596–69,715,144, 1 gene, copy number 10 (within-gene range 5–10): SUSD6.
- chr14:69,726,900–70,712,153, 28 genes, copy number 10 (within-gene range 6–10): SRSF5, SLC10A1, AL157789.1, SMOC1, RPL7AP6, SLC8A3, AL160191.1, AL160191.3, AL160191.2, ADAM21P1, AL356804.1, COX16, SYNJ2BP-COX16, RNU2-51P, SYNJ2BP, AL357153.2, ADAM21, ADAM20P1, RNU6-659P, ADAM20, AL357153.4, MED6, AL357153.3, KRT18P7, AL357153.1, RN7SL77P, TTC9, LINC01269.
- chr14:77,652,827–77,935,014, 9 genes, copy number 8: COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178, ADCK1, Y_RNA.
- chr14:85,911,438–90,491,637, 68 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr14:92,703,807–99,727,301, 147 genes, copy number 7–19 (broad region; genes not listed).
- chr22:18,873,543–21,551,461, 159 genes, copy number 12 (broad region; genes not listed).
- chr22:21,555,138–21,555,457, 1 gene, copy number 12: Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 92. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
